TCGA case TCGA-A4-A57E — Kidney Renal Papillary Cell Carcinoma (TCGA-KIRP)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Adenomas and Adenocarcinomas; Primary site: Kidney; Tissue source site: International Genomics Consortium. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/d80f601b-1064-4ff0-9c51-7f6afb22d1f5

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 59 years; Vital status: Dead; Days to death: 258 days.

Diagnoses (1)
1. Papillary adenocarcinoma, NOS: ICD-O-3 morphology code: 8260/3; ICD-10 code: C64.1; Tissue or organ of origin: Kidney, NOS; Site of resection or biopsy: Kidney, NOS; Laterality: Left; Classification of tumor: primary; Age at diagnosis: 59.9 years (21,885 days); Year of diagnosis: 2011; AJCC staging edition: 7th; AJCC clinical T: T1; AJCC clinical N: N0; AJCC clinical M: M1; AJCC clinical stage: Stage IV; AJCC pathologic T: T2a; AJCC pathologic N: N0; AJCC pathologic M: M1; AJCC pathologic stage: Stage IV; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Days to last follow up: 258 days.
   Pathology details: Consistent pathology review: No; Lymph nodes positive: 0; Lymph nodes tested: 1.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Everolimus; Days to treatment start: 39 days; Treatment outcome: Progressive Disease.

Follow-up (3 entries)
- Days to follow up: 258 days; Disease response: With Tumor.
- Karnofsky performance status: 90; ECOG performance status: 1; Timepoint: Other.
- Follow-up contact recording only the day: day 0.

Exposures
- Exposure type: Tobacco; Tobacco smoking status: Current Reformed Smoker for > 15 yrs; Pack years smoked: 50; Tobacco smoking onset year: 1968; Tobacco smoking quit year: 1993.

Biospecimens (4 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-A4-A57E-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Initial weight: 60 mg.
  Slide TCGA-A4-A57E-01A-01-TS1: Section location: Top; Percent tumor cells: 100; Percent tumor nuclei: 93; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 0; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-A4-A57E-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-A4-A57E-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.
- Sample TCGA-A4-A57E-11A: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Initial weight: 70 mg.
  Slide TCGA-A4-A57E-11A-01-TS1: Section location: Top; Percent tumor cells: 0; Percent tumor nuclei: 0; Percent normal cells: 100; Percent necrosis: 0; Percent stromal cells: 0; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Histologic diagnosis: Kidney Papillary Renal Cell Carcinoma; History neoadjuvant treatment: No; Prospective collection: Yes; Retrospective collection: No; Lymph nodes examined: Yes; Tobacco smoking history indicator: 3; New tumor event diagnosis indicator: No.
- Drug treatment: Pharmaceutical therapy drug name: Afinitor; Treatment best response: Clinical Progressive Disease.
- Follow-up form: Lost to follow-up: No; New tumor event diagnosis indicator: No; Tumor status: With tumor.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 258 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 258 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 258 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-A4-A57E-01A-11D-A26O-01): tumor purity 0.83, ploidy 2.04, whole-genome doublings 0.
